Somatic mutation profile of tumor specimen TCGA-FG-8185-01A (aliquot TCGA-FG-8185-01A-11D-2253-08) from TCGA case TCGA-FG-8185, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.3 years (13,621 days).
Specimen TCGA-FG-8185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e6000ed-7561-4f3b-bda2-4563fb4acfb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8185-10A (Blood Derived Normal), aliquot TCGA-FG-8185-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe4dc705-f0b6-4d68-b95e-139beb7703fb

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 27, Silent 10, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ADARB2 | c.60C>G p.C20W | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV67218145; called by muse, mutect2, varscan2
- AKAP8 | c.1312G>C p.V438L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV54101616; called by muse, mutect2
- AMIGO1 | c.950C>G p.T317R | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV63990297; called by muse, mutect2
- ANKRD11 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.772); catalogued as COSV56357337; called by muse, mutect2
- APOB | c.11434G>C p.E3812Q | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV51928026; called by muse, mutect2, varscan2
- COQ8B | c.1576G>C p.D526H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV53284692; called by muse, mutect2, varscan2
- CSNK1G2 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs1568207335, COSV55336392; called by muse, mutect2, varscan2
- FRMD7 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53745224; called by muse, mutect2
- GABRG2 | c.901G>T p.V301F (on ENST00000361925 / NM_001375343.1; = p.V261F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV62716203; called by muse, mutect2, varscan2
- GALC | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54323928; called by muse, mutect2, varscan2
- HEPACAM2 | c.855G>C p.R285S (on ENST00000394468 / NM_001039372.4; = p.R273S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV59058812; called by muse, mutect2, varscan2
- ICAM1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as rs748922559, COSV53424059; called by muse, mutect2, varscan2
- KCNB1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100870463, COSV65566826; called by muse, mutect2
- LIPC | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as rs1437322815, COSV54421118; called by muse, mutect2
- MDM2 | c.910T>C p.S304P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755429424, COSV50698273; called by muse, mutect2, varscan2
- MED23 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as rs1229061787, COSV63430612, COSV63431921; called by muse, mutect2, varscan2
- MMP20 | c.954G>C p.R318= | Splice Region (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52774541, COSV99498056; called by muse, mutect2, varscan2
- RBAK | c.1587C>G p.H529Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100806722; called by muse, mutect2, varscan2
- SLC17A6 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as COSV54134458; called by muse, mutect2, varscan2
- TCHH | c.1616G>C p.R539T | Missense Mutation (SNP) | VAF 22/346 reads (6%) | PolyPhen benign (0.278); catalogued as COSV64273674; called by muse, mutect2
- UGT2B10 | c.1396G>C p.V466L | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55319376; called by muse, mutect2
- VAX2 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52265366; called by muse, mutect2
- VIRMA | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs745403041, COSV52583045; called by muse, mutect2, varscan2
- ZNF460 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64415425; called by muse, mutect2, varscan2
- ABHD17B | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.02); called by muse, mutect2
- ATRX | c.833_834del p.T278Sfs*3 | Frame Shift Del (DEL) | VAF 58/94 reads (62%) | called by mutect2, pindel, varscan2
- TFPT | c.592_596dup p.R200Mfs*9 | Frame Shift Ins (INS) | VAF 62/169 reads (37%) | called by mutect2, varscan2
- AMPD1 | c.2139C>T p.C713= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs761985788, COSV62415411; called by muse, mutect2, varscan2
- CACNA1B | c.3717C>G p.S1239= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53118179; called by muse, mutect2, varscan2
- EFCAB5 | c.3462C>T p.Y1154= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as rs777050710, COSV57927317; called by muse, mutect2, varscan2
- LAMA1 | c.2604G>T p.G868= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV67533691, COSV67543344; called by muse, mutect2, varscan2
- MIA3 | c.2922C>G p.V974= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV60510801; called by muse, mutect2, varscan2
- MMP24 | c.1758C>T p.D586= | Silent (SNP) | VAF 100/257 reads (39%) | catalogued as rs370527619, COSV55768920; called by muse, mutect2, varscan2
- MYH7B | c.402G>A p.T134= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs1232234978, COSV53416526; called by muse, mutect2, varscan2
- PSME3IP1 | c.207C>T p.Y69= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as rs768449295, COSV58428763; called by muse, mutect2, varscan2
- SVEP1 | c.10452C>G p.R3484= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV52836905; called by muse, mutect2, varscan2
- VHL | c.615C>T p.R205= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV56545917, COSV56573502; called by muse, mutect2, varscan2
